CMI case MBCProject_0343 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/0989b286-04bb-434d-aa91-58d9018ccf49

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (5 samples)
- Sample MBCProject_0343_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCProject_0343_T1_RNA, MBCProject_0343_T1_WES, MBCProject_0343_T2_RNA, MBCProject_0343_T2_WES (4 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
